Somatic mutation profile of tumor specimen TCGA-AB-2821-03B (aliquot TCGA-AB-2821-03B-01W-0728-08) from TCGA case TCGA-AB-2821, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,527 days).
Specimen TCGA-AB-2821-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f1136ac-9d31-4854-b351-d10346db9d59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2821-11B (Solid Tissue Normal), aliquot TCGA-AB-2821-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94df78ce-f33d-4aab-aa2f-97e13376f1cc

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ATG16L1 | c.1673T>A p.L558Q (on ENST00000392017 / NM_030803.7; = p.L539Q on NM_017974.4) | Missense Mutation (SNP) | VAF 191/483 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61468681; called by muse, varscan2
- FAT2 | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV55831756; called by muse, mutect2, varscan2
- GALNT2 | c.1562A>C p.K521T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64198063; called by muse, varscan2
- GCNT4 | c.652A>T p.I218F | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100466246; called by muse, mutect2
- MFSD6 | c.228T>G p.F76L | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV55626092; called by muse, mutect2, varscan2
- NTRK3 | c.2084T>C p.I695T | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779320655, COSV62313214; called by muse, mutect2, varscan2
- R3HCC1L | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs573075515, COSV54406054; called by muse, mutect2, varscan2
- RUNX1 | c.285_286dup p.D96Gfs*11 (on ENST00000344691 / NM_001001890.3; = p.D123Gfs*11 on NM_001754.5) | Frame Shift Ins (INS) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- UBR5 | c.6360dup p.E2121Rfs*13 | Frame Shift Ins (INS) | VAF 61/208 reads (29%) | called by mutect2, varscan2
- OR8H2 | c.516C>T p.N172= | Silent (SNP) | VAF 182/485 reads (38%) | catalogued as rs763293702, COSV57944151; called by muse, mutect2, varscan2
- RUNX1T1 | c.450C>T p.T150= (on ENST00000265814 / NM_001198628.1; = p.T123= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/306 reads (34%) | catalogued as COSV56166408; called by muse, mutect2, varscan2
- STK24 | c.1295+662G>A | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as rs766618839; called by muse, mutect2, varscan2
